Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3488, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3488-01A (Primary Tumor).

Diagnosis/Diagnoses:

Colonic resection specimen (rectosigmoid junction) including a tubular adenoma with focal severe dysplasia and transitions to adenocarcinoma in situ (synonym: high-grade intra-epithelial neoplasia) with ulcerated, moderately to poorly differentiated adenocarcinoma with incipient infiltration of the perimuscular fat tissue (G2 to 3, pT3) (cf. preliminary biopsy findings [REDACTED] and with tumor-free oral and aboral margins.

Follow-up report:

Twenty-six lymph nodes of up to 0.9 cm in size in the vicinity of the tumor were dissected out from the pericolic fatty tissue after clarification with acetone.

Fifteen of these exhibit metastatic infiltrates from the previously diagnosed adenocarcinoma or colon carcinoma.

In conclusion or in summary, therefore, a stage of T3 pN2 (15/26) is established.

Source: NCI Genomic Data Commons file e2fc5df1-ee9d-404f-8e7d-18ed446eecdb (TCGA-AA-3488.C922524E-B1D2-4EC6-9D52-1C649CFBBB4B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).